Somatic mutation profile of tumor specimen TCGA-55-A491-01A (aliquot TCGA-55-A491-01A-11D-A24D-08) from TCGA case TCGA-55-A491, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 81.0 years (29,593 days).
Specimen TCGA-55-A491-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4abb8190-8ea6-4b4b-8fd3-5d4d3c33e2bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A491-10A (Blood Derived Normal), aliquot TCGA-55-A491-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/772f526f-f372-485c-a15b-4837826c1446

The open-access MAF lists 406 somatic variants for this specimen: 305 protein-altering or splice-affecting, 94 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 264, Silent 94, Nonsense Mutation 22, Splice Site 9, Frame Shift Del 7, RNA 4, Frame Shift Ins 2, Intron 2, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HSD11B1 | c.133G>T p.G45W | Missense Mutation (SNP) | VAF 17/72 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54825714, COSV99808085; called by muse, mutect2, varscan2
- RRAS2 | c.215A>T p.Q72L | Missense Mutation (SNP) | VAF 200/270 reads (74%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as rs113954997, COSV56329169; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.578A>G p.H193R | Missense Mutation (SNP) | VAF 20/43 reads (47%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AASS | c.1366C>T p.P456S | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV100741763, COSV62792580; called by muse, mutect2, varscan2
- ABCB5 | c.2893G>T p.A965S (on ENST00000404938 / NM_001163941.2; = p.A520S on NM_178559.6) | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as COSV51709780; called by muse, mutect2, varscan2
- ABCD2 | c.1619C>A p.P540H | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as COSV100429374; called by muse, mutect2, varscan2
- ACSM2A | c.1073G>C p.R358P (on ENST00000219054; = p.R279P on NM_001308169.2) | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs188648395, COSV54581766, COSV99525176; called by muse, mutect2, varscan2
- ACTRT1 | c.666C>G p.I222M | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV64418931, COSV64419524; called by muse, mutect2, varscan2
- ADGRD1 | c.2577G>A p.W859* | Nonsense Mutation (SNP) | VAF 9/42 reads (21%) | catalogued as COSV99895154; called by muse, mutect2, varscan2
- ADGRE1 | c.1848C>A p.C616* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | catalogued as COSV99165223, COSV99165327; called by muse, mutect2, varscan2
- ADNP2 | c.770G>A p.R257K | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760494033, COSV100080780; called by muse, mutect2, varscan2
- ANK2 | c.3755G>T p.G1252V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100000096; called by muse, mutect2
- ANKRD55 | c.1022G>A p.R341K | Missense Mutation (SNP) | VAF 43/126 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.018); catalogued as COSV100591244; called by muse, mutect2, varscan2
- ANTXR1 | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.901); catalogued as COSV100362389; called by muse, mutect2, varscan2
- AP5Z1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100804102; called by muse, mutect2, varscan2
- ARFGEF2 | c.3974G>T p.W1325L | Missense Mutation (SNP) | VAF 37/81 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100904230; called by muse, mutect2, varscan2
- ARHGAP1 | c.792G>T p.R264S | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.081); catalogued as COSV100357900; called by muse, mutect2, varscan2
- ARHGEF11 | c.3856G>T p.E1286* | Nonsense Mutation (SNP) | VAF 17/44 reads (39%) | catalogued as COSV100168521, COSV59357810; called by muse, mutect2, varscan2
- ARHGEF4 | c.1283G>C p.C428S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100387989; called by muse, mutect2, varscan2
- ARHGEF9 | c.382-2A>T p.X128_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | catalogued as COSV99491690; called by muse, mutect2, varscan2
- ARHGEF9 | c.81G>T p.L27F | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99491692; called by muse, mutect2, varscan2
- ARMC3 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99957937; called by muse, mutect2, varscan2
- ARMC4 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.225); catalogued as COSV100536672, COSV59461933; called by muse, mutect2, varscan2
- ASB3 | c.525G>T p.Q175H | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.54); PolyPhen benign (0.113); catalogued as COSV55081728; called by muse, mutect2, varscan2
- ATP1A2 | c.2143G>T p.G715W | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111486, COSV100767794; called by muse, mutect2, varscan2
- ATP4A | c.2107C>T p.R703C | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776225963, CM153264, COSV52865187; called by muse, mutect2, varscan2
- ATRNL1 | c.2560G>C p.A854P | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.046); catalogued as COSV100370352; called by muse, mutect2, varscan2
- BAAT | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV99408459; called by muse, mutect2, varscan2
- BAIAP2L2 | c.994C>G p.L332V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.27); catalogued as COSV101091922; called by muse, mutect2
- BBS7 | c.986G>T p.G329V | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV99144893; called by muse, mutect2, varscan2
- BBS7 | c.985G>T p.G329* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99144894; called by muse, mutect2, varscan2
- BCLAF3 | c.1418A>T p.Q473L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100503283; called by muse, mutect2, varscan2
- BRSK1 | c.1241C>T p.P414L | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100473977; called by muse, mutect2, varscan2
- BTN3A2 | c.676C>T p.L226F | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100709629; called by muse, mutect2, varscan2
- C12orf42 | c.597G>C p.K199N | Missense Mutation (SNP) | VAF 75/217 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.114); catalogued as COSV100172119; called by muse, mutect2, varscan2
- C6 | c.2443G>T p.A815S | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.64); PolyPhen benign (0.027); catalogued as COSV54711296; called by muse, mutect2, varscan2
- CACNA1H | c.4202T>A p.L1401Q | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99049013; called by muse, mutect2
- CACNG3 | c.491C>A p.P164H | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99135972; called by muse, mutect2, varscan2
- CCDC170 | c.1804A>C p.M602L | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as COSV99498372; called by muse, mutect2, varscan2
- CCDC180 | c.1677C>A p.H559Q | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV100826660; called by muse, mutect2, varscan2
- CCDC88A | c.5422G>T p.V1808L (on ENST00000436346 / NM_001365480.1; = p.V1780L on NM_018084.5) | Missense Mutation (SNP) | VAF 43/96 reads (45%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.603); catalogued as COSV99710296; called by muse, mutect2, varscan2
- CCER1 | c.1156C>A p.P386T | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV100726971, COSV100727016; called by muse, mutect2
- CCER1 | c.442C>A p.R148S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as COSV100727017; called by muse, mutect2, varscan2
- CD200R1 | c.802G>A p.G268S (on ENST00000471858 / NM_170780.3; = p.G291S on NM_138806.4) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.21); PolyPhen benign (0.124); catalogued as COSV99867140; called by muse, mutect2, varscan2
- CD96 | c.1579G>T p.A527S (on ENST00000283285 / NM_198196.3; = p.A511S on NM_005816.5) | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV99342789; called by muse, mutect2, varscan2
- CDH18 | c.875C>A p.A292E | Missense Mutation (SNP) | VAF 61/120 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99934222; called by muse, mutect2, varscan2
- CEP126 | c.1783A>G p.I595V | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.32); PolyPhen benign (0.036); catalogued as COSV99680973; called by muse, mutect2
- CEP135 | c.2113G>T p.E705* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | catalogued as COSV99954369; called by muse, mutect2, varscan2
- CEP135 | c.2523G>T p.L841F | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV99954370; called by muse, mutect2, varscan2
- CEP83 | c.705G>T p.K235N | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.131); catalogued as COSV100352818; called by muse, mutect2, varscan2
- CEP83 | c.346G>C p.E116Q | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100352822; called by muse, mutect2, varscan2
- CFAP61 | c.263T>A p.F88Y | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV99844527; called by muse, mutect2
- CFAP65 | c.1593C>A p.F531L | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs766124553, COSV99838311; called by muse, mutect2, varscan2
- CHD9 | c.1317G>C p.Q439H | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV101272098; called by muse, mutect2, varscan2
- CHEK2 | c.1267C>G p.L423V (on ENST00000382580 / NM_001005735.2; = p.L380V on NM_007194.4) | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV100101533; called by muse, mutect2, varscan2
- CLEC2B | c.203C>T p.A68V | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); catalogued as rs866500641, COSV99946959; called by muse, mutect2
- CLINT1 | c.1398G>C p.Q466H | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0.135); catalogued as COSV99753887; called by muse, mutect2, varscan2
- CLIP1 | c.2698G>C p.E900Q (on ENST00000620786 / NM_001247997.1; = p.E889Q on NM_002956.2) | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.045); catalogued as COSV100211596; called by muse, mutect2
- CMTR2 | c.2224T>G p.L742V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV100579112; called by muse, mutect2
- COL11A1 | c.2375T>G p.M792R | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as rs1244260470, COSV100616199; called by muse, mutect2
- COL24A1 | c.988C>A p.H330N | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV100993204, COSV65301851; called by muse, mutect2, varscan2
- CRISP2 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 20/114 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV59254437; called by muse, mutect2, varscan2
- CRISPLD1 | c.836G>C p.S279T | Missense Mutation (SNP) | VAF 92/221 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV100081909; called by muse, mutect2, varscan2
- CSMD3 | c.10669T>A p.Y3557N (on ENST00000297405 / NM_001363185.1; = p.Y3388N on NM_052900.3) | Missense Mutation (SNP) | VAF 62/207 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV99832567; called by muse, mutect2, varscan2
- CSMD3 | c.10480G>T p.V3494L (on ENST00000297405 / NM_001363185.1; = p.V3325L on NM_052900.3) | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.741); catalogued as rs866015702, COSV52311928; called by muse, mutect2, varscan2
- CSMD3 | c.6766T>A p.L2256I (on ENST00000297405 / NM_001363185.1; = p.L2152I on NM_052900.3) | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV99832573; called by muse, mutect2, varscan2
- CSMD3 | c.3872G>A p.G1291E (on ENST00000297405 / NM_001363185.1; = p.G1187E on NM_052900.3) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as COSV52114275, COSV52269703; called by muse, mutect2
- CTSV | c.538G>C p.G180R | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99414364; called by mutect2, varscan2
- CUL4B | c.2505A>T p.Q835H | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.115); catalogued as COSV100340444, COSV60688744; called by muse, mutect2, varscan2
- DCAF12L1 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.488); catalogued as rs757985768, COSV100948252, COSV64421466; called by muse, mutect2, varscan2
- DCAF4L2 | c.8G>T p.S3I | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as COSV100150815; called by muse, mutect2, varscan2
- DDB1 | c.1117G>T p.G373W | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100074533; called by muse, mutect2, varscan2
- DNAH11 | c.9036T>A p.H3012Q | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.92); catalogued as COSV100179000; called by muse, mutect2
- DNASE2 | c.664G>T p.G222W | Missense Mutation (SNP) | VAF 26/85 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99262800; called by muse, mutect2, varscan2
- EHMT1 | c.2113G>C p.G705R | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.06); catalogued as COSV58380156; called by muse, mutect2, varscan2
- EHMT1 | c.2114G>T p.G705V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV100603704; called by muse, mutect2, varscan2
- EPHA6 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 61/289 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as rs760349835, COSV101062231; called by muse, mutect2, varscan2
- ERBB3 | c.1777G>T p.V593F | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.057); catalogued as COSV57247661; called by muse, mutect2, varscan2
- ERICH3 | c.2014G>A p.G672R | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.083); catalogued as COSV58599107; called by muse, mutect2, varscan2
- FABP3 | c.5T>C p.V2A | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV101038388; called by muse, mutect2, varscan2
- FAM120C | c.1678T>C p.S560P | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as COSV100069952; called by muse, varscan2
- FAM135B | c.3137C>T p.S1046F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.03); catalogued as COSV52704222, COSV99422994; called by muse, mutect2, varscan2
- FAM193A | c.3427G>T p.E1143* | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100219037, COSV100219291; called by muse, mutect2, varscan2
- FAM83B | c.220A>T p.S74C | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.018); catalogued as COSV100174370; called by muse, mutect2, varscan2
- FAT3 | c.11096T>A p.L3699Q | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV99965312; called by mutect2, varscan2
- FGB | c.1417T>A p.S473T | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.738); catalogued as rs1243986153, COSV100122425; called by muse, mutect2, varscan2
- FLNC | c.841T>A p.Y281N | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100367991; called by muse, mutect2
- FLT1 | c.387T>A p.S129R | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as COSV99152466; called by muse, mutect2, varscan2
- FOXD3 | c.734T>A p.L245Q | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.795); catalogued as COSV100942850; called by muse, mutect2, varscan2
- FOXJ3 | c.884C>T p.S295L | Missense Mutation (SNP) | VAF 79/203 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100691699; called by muse, mutect2, varscan2
- FOXR2 | c.707G>T p.W236L | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100189481; called by muse, mutect2, varscan2
- FRMPD4 | c.2701C>A p.P901T | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101042718, COSV66224052; called by muse, mutect2, varscan2
- FUT11 | c.657C>G p.D219E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); catalogued as COSV100226758; called by muse, mutect2, varscan2
- FUT9 | c.330C>A p.H110Q | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100133476; called by muse, mutect2, varscan2
- GABRG2 | c.1246C>A p.P416T (on ENST00000361925 / NM_001375343.1; = p.P376T on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV100729660; called by muse, mutect2, varscan2
- GABRG2 | c.1247C>A p.P416H (on ENST00000361925 / NM_001375343.1; = p.P376H on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as COSV100729767, COSV62717547; called by muse, mutect2, varscan2
- GAP43 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as COSV100525525; called by muse, mutect2, varscan2
- GAS2L3 | c.2015C>G p.P672R | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.068); catalogued as COSV99902824; called by muse, mutect2, varscan2
- GBA2 | c.712G>A p.V238I | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100803373; called by muse, mutect2, varscan2
- GCC2 | c.306G>A p.M102I | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100565410; called by muse, mutect2, varscan2
- GDPD4 | c.472T>A p.L158I | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.396); catalogued as COSV100265243; called by muse, mutect2
- GFOD1 | c.424G>T p.E142* | Nonsense Mutation (SNP) | VAF 11/58 reads (19%) | catalogued as COSV101015044; called by muse, mutect2, varscan2
- GFRAL | c.601T>A p.S201T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.406); catalogued as COSV100475054; called by muse, mutect2, varscan2
- GH2 | c.74G>C p.S25T | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.026); catalogued as COSV100236948; called by muse, mutect2, varscan2
- GLI3 | c.4502G>T p.G1501V | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV101229830; called by muse, mutect2, varscan2
- GNB4 | c.1000A>T p.S334C | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV99224203; called by muse, mutect2, varscan2
- GPRIN1 | c.1969G>T p.V657L | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99991490; called by muse, mutect2, varscan2
- GREB1 | c.1576G>A p.A526T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV99302821; called by muse, mutect2
- GRK7 | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV99379804; called by muse, mutect2, varscan2
- GRN | c.1360C>T p.Q454* | Nonsense Mutation (SNP) | VAF 39/99 reads (39%) | catalogued as COSV99274781; called by muse, mutect2, varscan2
- H4C6 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV100897487; called by muse, mutect2, varscan2
- HACE1 | c.932G>T p.S311I | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99493608; called by muse, mutect2, varscan2
- HDAC9 | c.3178G>C p.G1060R (on ENST00000441542 / NM_178425.3; = p.G1057R on NM_178423.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.653); catalogued as COSV101286721, COSV67770854, COSV67787716; called by muse, mutect2, varscan2
- HKDC1 | c.351A>T p.E117D | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV100664524; called by muse, mutect2
- HLA-A | c.754A>C p.T252P | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100954376; called by mutect2, varscan2
- HOXA2 | c.443C>A p.T148N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV99761159; called by muse, mutect2, varscan2
- IGKV1-8 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 37/201 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs1239351171; called by muse, mutect2, varscan2
- IGLV5-45 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 40/188 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.083); catalogued as rs545003867; called by muse, varscan2
- IL18R1 | c.517A>T p.K173* | Nonsense Mutation (SNP) | VAF 7/43 reads (16%) | catalogued as COSV99295039; called by muse, mutect2
- IL1RAPL1 | c.901A>C p.S301R | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV100146856; called by muse, mutect2, varscan2
- ITGAL | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 20/110 reads (18%) | catalogued as COSV100776226; called by muse, mutect2, varscan2
- KANK1 | c.3115G>C p.E1039Q | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.081); catalogued as COSV100619699; called by muse, mutect2, varscan2
- KATNIP | c.3854G>A p.W1285* | Nonsense Mutation (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99850894; called by muse, mutect2, varscan2
- KCNB2 | c.175A>T p.T59S | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.68); catalogued as COSV101578757; called by muse, mutect2, varscan2
- KCNC2 | c.1457A>G p.K486R | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.58); PolyPhen benign (0.074); catalogued as rs1485533102, COSV100128696; called by muse, mutect2, varscan2
- KCNH7 | c.3011C>A p.P1004H | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0.039); catalogued as COSV100147745; called by muse, mutect2, varscan2
- KCNRG | c.48C>G p.F16L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.902); catalogued as COSV53948800, COSV53949445; called by muse, mutect2, varscan2
- KCNT2 | c.3226C>A p.H1076N | Missense Mutation (SNP) | VAF 59/229 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs767642359, COSV99038393, COSV99653888; called by muse, mutect2, varscan2
- KIAA0100 | c.2690T>A p.M897K | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101197290; called by muse, mutect2, varscan2
- KMT2A | c.2381C>T p.P794L | Missense Mutation (SNP) | VAF 22/142 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.441); catalogued as COSV100628617; called by muse, mutect2, varscan2
- KRT5 | c.1262G>C p.G421A | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs761706455, COSV99357979; called by muse, mutect2, varscan2
- KRTAP10-4 | c.701G>A p.C234Y | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs1467336415, COSV100553220; called by muse, mutect2, varscan2
- KRTAP10-6 | c.574G>A p.E192K | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0.03); catalogued as rs587631268, COSV100553221; called by muse, mutect2, varscan2
- KRTAP5-1 | c.578C>A p.S193Y | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.367); catalogued as COSV66298960; called by muse, varscan2
- LAMA2 | c.688C>A p.P230T | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs779421508, COSV101370398; called by muse, mutect2, varscan2
- LAMA5 | c.5773G>T p.A1925S | Missense Mutation (SNP) | VAF 11/16 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99439584; called by muse, mutect2, varscan2
- LAS1L | c.1498C>G p.L500V | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100408541; called by muse, mutect2, varscan2
- LGALS14 | c.401G>T p.R134I | Missense Mutation (SNP) | VAF 80/124 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); catalogued as COSV100648425, COSV62372145; called by muse, mutect2
- LMO7 | c.2337G>T p.K779N (on ENST00000357063; = p.K460N on NM_005358.5) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as COSV100413003; called by muse, mutect2, varscan2
- LPAR3 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868775620, COSV101004636; called by muse, mutect2
- LRIG3 | c.2681A>T p.Q894L | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0.261); catalogued as COSV100292588; called by muse, mutect2, varscan2
- MAEL | c.261G>T p.M87I | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.007); catalogued as COSV100901825; called by muse, mutect2, varscan2
- MAGEA8 | c.892G>T p.A298S | Missense Mutation (SNP) | VAF 70/156 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.069); catalogued as COSV99674554; called by muse, mutect2, varscan2
- MAGEB4 | c.469C>G p.R157G | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.275); catalogued as COSV100974936, COSV66775145, COSV66776087; called by muse, mutect2, varscan2
- MEGF10 | c.1517C>T p.A506V | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.752); catalogued as COSV99174889; called by muse, mutect2, varscan2
- MICAL3 | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 9/130 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV99261295; called by muse, mutect2
- MKI67 | c.6870G>T p.L2290F | Missense Mutation (SNP) | VAF 33/272 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV100896454; called by muse, mutect2, varscan2
- MLLT10 | c.2056T>G p.S686A (on ENST00000307729 / NM_001195626.3; = p.S702A on NM_004641.3) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV100307986; called by muse, mutect2
- MMP2 | c.550T>C p.F184L | Missense Mutation (SNP) | VAF 46/118 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99527712; called by muse, mutect2, varscan2
- MPPED2 | c.225G>T p.M75I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.8); PolyPhen benign (0.103); catalogued as COSV100813247; called by muse, mutect2, varscan2
- MRC1 | c.745C>A p.Q249K | Missense Mutation (SNP) | VAF 24/162 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100509585; called by muse, mutect2, varscan2
- MS4A1 | c.505C>T p.P169S | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV100619316; called by muse, mutect2, varscan2
- MS4A14 | c.1730C>A p.P577Q | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT tolerated (0.49); PolyPhen benign (0.099); catalogued as COSV100280330; called by muse, mutect2, varscan2
- MUC16 | c.33241G>C p.A11081P | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV101199599, COSV67480334; called by muse, mutect2, varscan2
- MYH2 | c.1975G>T p.E659* | Nonsense Mutation (SNP) | VAF 12/32 reads (38%) | catalogued as COSV55446781, COSV99819990; called by muse, mutect2, varscan2
- NBAS | c.5488G>T p.V1830F | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs764915419, COSV99869085; called by muse, mutect2, varscan2
- NCKAP5 | c.853T>C p.S285P | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as COSV100491569; called by muse, mutect2
- NEDD1 | c.489+1G>T p.X163_splice | Splice Site (SNP) | VAF 30/93 reads (32%) | catalogued as COSV99900965; called by muse, mutect2, varscan2
- NLGN4X | c.841G>T p.G281C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52004121, COSV99321427; called by muse, mutect2, varscan2
- NLGN4X | c.186A>T p.L62F | Missense Mutation (SNP) | VAF 28/118 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.992); catalogued as COSV99321430; called by muse, mutect2, varscan2
- NLRC5 | c.4127G>T p.G1376V | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV99347099; called by muse, mutect2, varscan2
- NLRP12 | c.1396G>C p.A466P | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100145181; called by muse, mutect2
- NRXN3 | c.3204G>T p.W1068C (on ENST00000335750 / NM_001330195.2; = p.W695C on NM_004796.6) | Missense Mutation (SNP) | VAF 32/69 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100203250, COSV59797927; called by muse, mutect2, varscan2
- NUMBL | c.430G>T p.V144F | Missense Mutation (SNP) | VAF 213/362 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99424891; called by muse, mutect2, varscan2
- ODAPH | c.323A>G p.H108R | Missense Mutation (SNP) | VAF 25/167 reads (15%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100290159; called by muse, mutect2, varscan2
- OR10V1 | c.839C>A p.T280K | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100275811; called by muse, mutect2, varscan2
- OR10W1 | c.96del p.N33Tfs*95 | Frame Shift Del (DEL) | VAF 16/69 reads (23%) | catalogued as COSV67720403; called by mutect2, pindel, varscan2
- OR14J1 | c.715T>A p.C239S | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101012767; called by muse, mutect2, varscan2
- OR51D1 | c.88C>A p.P30T | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV100712371; called by muse, mutect2, varscan2
- OR5AN1 | c.116C>A p.S39Y | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as rs777894055, COSV58321780; called by muse, mutect2, varscan2
- OR8H1 | c.702G>T p.Q234H | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV100477048; called by muse, mutect2, varscan2
- OTOF | c.706A>C p.K236Q | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99717459; called by muse, mutect2, varscan2
- P2RX2 | c.991G>T p.G331* (on ENST00000343948 / NM_170683.4; = p.G259* on NM_012226.5) | Nonsense Mutation (SNP) | VAF 70/159 reads (44%) | catalogued as COSV100266305, COSV57686947; called by muse, mutect2, varscan2
- PAPPA | c.3535C>A p.R1179S | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100073847; called by muse, mutect2, varscan2
- PCDH11X | c.1300A>T p.I434F | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.208); catalogued as COSV100011272; called by muse, mutect2, varscan2
- PCDH15 | c.4471G>T p.E1491* | Nonsense Mutation (SNP) | VAF 24/66 reads (36%) | catalogued as COSV100219814; called by muse, mutect2, varscan2
- PCDH7 | c.3118G>C p.G1040R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100687820, COSV100688077; called by muse, mutect2, varscan2
- PCDHAC1 | c.688G>T p.A230S | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT tolerated (0.24); PolyPhen benign (0.333); catalogued as COSV53852424, COSV99165932; called by muse, mutect2, varscan2
- PCDHGA1 | c.2209G>T p.G737C | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as rs113017417, COSV100965987, COSV65298148; called by muse, mutect2, varscan2
- PCDHGA3 | c.58C>A p.L20M | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.745); catalogued as COSV99536798; called by muse, mutect2, varscan2
- PKD1L1 | c.4035G>T p.W1345C | Missense Mutation (SNP) | VAF 15/118 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV99219433, COSV99221153; called by muse, mutect2, varscan2
- PLA1A | c.1121+2T>A p.X374_splice | Splice Site (SNP) | VAF 16/51 reads (31%) | catalogued as COSV99845824; called by muse, mutect2
- PLCB4 | c.1015G>T p.G339W | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53798533, COSV99595264; called by muse, mutect2, varscan2
- PLXNA3 | c.5431G>T p.V1811L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV100859928; called by muse, mutect2, varscan2
- POM121L12 | c.701G>T p.G234V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101374908; called by muse, mutect2, varscan2
- POP7 | c.342G>C p.E114D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs1280640535, COSV100292171; called by muse, mutect2, varscan2
- PRKCA | c.1151C>T p.T384I | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.989); catalogued as COSV99434465; called by muse, mutect2, varscan2
- PRRC2A | c.1851A>T p.E617D | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as COSV101051153; called by muse, mutect2, varscan2
- PRSS58 | c.215C>A p.A72E | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.173); catalogued as COSV101616124, COSV73488444; called by muse, mutect2, varscan2
- PRXL2C | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV100925126; called by muse, mutect2, varscan2
- PTBP3 | c.46G>T p.G16* | Nonsense Mutation (SNP) | VAF 18/78 reads (23%) | catalogued as COSV99270232; called by muse, mutect2, varscan2
- PTPRC | c.1289C>G p.T430R | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.46); PolyPhen benign (0.079); catalogued as COSV100722548; called by muse, mutect2, varscan2
- PTPRN | c.1632G>C p.Q544H | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.722); catalogued as COSV55347262, COSV99833945; called by muse, mutect2, varscan2
- QRFPR | c.988A>T p.I330F | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.052); catalogued as COSV100543694; called by muse, mutect2
- R3HCC1L | c.140T>C p.V47A | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.043); catalogued as COSV100107305; called by muse, mutect2, varscan2
- RANBP2 | c.6288G>T p.K2096N | Missense Mutation (SNP) | VAF 76/446 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.087); catalogued as COSV99311966; called by muse, mutect2, varscan2
- RAPGEF2 | c.3731G>T p.S1244I | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); catalogued as COSV100031028; called by muse, mutect2
- RAPGEF2 | c.3733G>T p.G1245C | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); catalogued as COSV100031029; called by muse, mutect2
- RASGEF1B | c.928+2T>G p.X310_splice | Splice Site (SNP) | VAF 6/94 reads (6%) | catalogued as COSV100020945; called by muse, mutect2
- RBM10 | c.1716C>A p.Y572* | Nonsense Mutation (SNP) | VAF 18/70 reads (26%) | catalogued as COSV100237692; called by muse, mutect2, varscan2
- RBM26 | c.2080C>G p.L694V (on ENST00000438737 / NM_001366735.2; = p.L667V on NM_022118.5) | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.82); catalogued as COSV99936078; called by muse, mutect2, varscan2
- RBSN | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as COSV99515186; called by muse, mutect2, varscan2
- RC3H1 | c.3326T>C p.L1109P | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); catalogued as COSV99281305; called by muse, mutect2
- RFPL3 | c.836T>A p.L279Q (on ENST00000249007 / NM_001098535.1; = p.L250Q on NM_006604.2) | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99967052; called by muse, mutect2, varscan2
- RFX5 | c.266A>G p.Y89C | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs750713961, COSV100923868; called by muse, mutect2, varscan2
- RGS7 | c.1042C>A p.L348I | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.86); catalogued as COSV100466835, COSV100469032; called by muse, mutect2, varscan2
- RIBC1 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.137); catalogued as COSV99394940; called by muse, mutect2, varscan2
- RNF152 | c.6G>T p.E2D | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV100455130; called by muse, mutect2, varscan2
- RRAGC | c.1153A>T p.S385C | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.379); catalogued as COSV100883821; called by muse, mutect2, varscan2
- SCN5A | c.2614G>A p.D872N | Missense Mutation (SNP) | VAF 25/107 reads (23%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.936); catalogued as rs763396298, COSV61117571; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDE2 | c.22G>C p.V8L | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.283); catalogued as COSV99682641; called by muse, mutect2, varscan2
- SESTD1 | c.1438C>G p.Q480E | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen possibly damaging (0.585); catalogued as COSV100090444; called by muse, mutect2
- SFTPA1 | c.481C>A p.R161S | Missense Mutation (SNP) | VAF 74/269 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100956993; called by muse, mutect2, varscan2
- SHROOM2 | c.3079C>A p.P1027T | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV101098492; called by muse, mutect2, varscan2
- SHROOM4 | c.851A>T p.Q284L | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV99173342; called by muse, mutect2, varscan2
- SIRPG | c.715C>T p.R239C | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs771425697, COSV53805725, COSV53806906; called by muse, mutect2, varscan2
- SLC13A5 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99545862; called by muse, mutect2, varscan2
- SLC22A9 | c.1652C>T p.T551M | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs142543443, CM124408; called by muse, mutect2, varscan2
- SLC4A1 | c.1605G>T p.E535D | Missense Mutation (SNP) | VAF 27/73 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99293282; called by muse, mutect2, varscan2
- SLC4A7 | c.1883G>T p.G628V | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99839646; called by muse, mutect2, varscan2
- SLC5A9 | c.2041G>C p.A681P | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.049); catalogued as COSV99361595; called by muse, mutect2, varscan2
- SLIT3 | c.1694G>A p.S565N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); catalogued as COSV100267060; called by muse, mutect2, varscan2
- SLITRK2 | c.2068C>A p.P690T | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (1); PolyPhen possibly damaging (0.635); catalogued as COSV59424218, COSV59430161; called by muse, mutect2, varscan2
- SMAD3 | c.686C>T p.P229L | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1232187684, COSV59289407; ClinVar: uncertain significance; called by muse, mutect2
- SNX30 | c.296A>G p.K99R | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100953846; called by muse, mutect2, varscan2
- SPIN2B | c.445G>T p.G149W | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99328151; called by muse, mutect2, varscan2
- SPSB4 | c.768C>G p.D256E | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100141252; called by muse, mutect2, varscan2
- SRPK2 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 12/80 reads (15%) | catalogued as COSV100623897; called by muse, mutect2, varscan2
- STK36 | c.2834C>T p.S945F | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.293); catalogued as rs1162811701, COSV99831284, COSV99831386; called by muse, mutect2, varscan2
- STK4 | c.382A>G p.T128A | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.017); catalogued as COSV100860081; called by muse, mutect2, varscan2
- STXBP5L | c.783G>T p.E261D | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99873696; called by muse, mutect2, varscan2
- SUGP2 | c.2732G>T p.G911V | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100431843; called by muse, mutect2, varscan2
- TBX22 | c.1282G>C p.D428H | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV100960753, COSV64787571; called by muse, mutect2, varscan2
- TECR | c.350A>G p.Y117C | Missense Mutation (SNP) | VAF 49/206 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.885); catalogued as rs1463368913, COSV99295071; called by muse, mutect2, varscan2
- TENM2 | c.6991C>G p.R2331G (on ENST00000518659 / NM_001122679.2; = p.R2092G on NM_001080428.3) | Missense Mutation (SNP) | VAF 85/192 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101318567; called by muse, mutect2, varscan2
- TENT5D | c.601G>T p.V201F | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.309); catalogued as COSV100382689, COSV57638597; called by muse, mutect2, varscan2
- THSD7B | c.3851A>T p.E1284V (on ENST00000272643; = p.E1282V on NM_001316349.2) | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.857); catalogued as COSV99749387; called by muse, mutect2, varscan2
- TIAM2 | c.4106C>T p.S1369F (on ENST00000529824; = p.S1340F on NM_012454.3) | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs560894259, COSV99265389; called by muse, mutect2, varscan2
- TICRR | c.3361C>G p.P1121A | Missense Mutation (SNP) | VAF 14/160 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.168); catalogued as COSV51546535; called by muse, mutect2
- TMEM38B | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1411772141, COSV101016295; called by muse, mutect2, varscan2
- TMEM74 | c.346A>C p.K116Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.036); catalogued as COSV99865633; called by muse, mutect2, varscan2
- TMPRSS11E | c.16G>A p.D6N | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as COSV100542336; called by muse, mutect2, varscan2
- TMTC1 | c.731+1G>T p.X244_splice (on ENST00000539277 / NM_001193451.2; = p.X136_splice on NM_175861.3) | Splice Site (SNP) | VAF 18/62 reads (29%) | catalogued as COSV99759467; called by muse, mutect2, varscan2
- TP53TG5 | c.644C>A p.P215H | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101022339; called by muse, mutect2, varscan2
- TRIM24 | c.2525A>G p.E842G (on ENST00000343526 / NM_015905.3; = p.E808G on NM_003852.4) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100630905; called by muse, mutect2, varscan2
- TRIM4 | c.760G>T p.G254W | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.717); catalogued as COSV100584263; called by muse, mutect2, varscan2
- TRIM51 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.119); catalogued as COSV99792514; called by muse, varscan2
- TSHZ1 | c.303G>T p.Q101H (on ENST00000580243 / NM_001308210.2; = p.Q56H on NM_005786.6) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.112); catalogued as COSV100433590; called by muse, mutect2, varscan2
- TTN | c.62861C>A p.T20954N (on ENST00000591111; = p.T13530N on NM_003319.4) | Missense Mutation (SNP) | VAF 20/89 reads (22%) | PolyPhen benign (0.372); catalogued as COSV100609936; called by muse, mutect2, varscan2
- TTN | c.50083G>T p.V16695L (on ENST00000591111; = p.V9271L on NM_003319.4) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | PolyPhen benign (0.243); catalogued as COSV100609938; called by muse, mutect2, varscan2
- UBQLN2 | c.1241C>G p.P414R | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100592700, COSV100592824; called by muse, mutect2, varscan2
- UNC45B | c.1964+2T>C p.X655_splice | Splice Site (SNP) | VAF 20/62 reads (32%) | catalogued as COSV99268621; called by muse, mutect2, varscan2
- USP53 | c.1309C>G p.Q437E | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV99917665; called by muse, mutect2
- VPS35 | c.280C>T p.L94F | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100140607; called by muse, mutect2, varscan2
- VSIR | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.734); catalogued as COSV56481592; called by muse, mutect2, varscan2
- WAS | c.335C>A p.P112H | Missense Mutation (SNP) | VAF 4/11 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1458417951, COSV100939483; called by muse, mutect2
- WDR92 | c.867-1G>T p.X289_splice | Splice Site (SNP) | VAF 28/73 reads (38%) | catalogued as COSV99718271; called by muse, mutect2, varscan2
- WNT7A | c.845C>A p.P282Q | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (0.55); PolyPhen benign (0.347); catalogued as COSV99541248; called by muse, mutect2, varscan2
- WWC3 | c.1852C>A p.L618I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.622); catalogued as COSV101081386; called by muse, mutect2, varscan2
- XK | c.56C>A p.T19K | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.203); catalogued as COSV101064625, COSV66119868; called by muse, mutect2, varscan2
- XRCC6 | c.1291G>T p.G431C | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100777817; called by muse, mutect2, varscan2
- ZBBX | c.2104G>T p.E702* | Nonsense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as COSV100283859; called by muse, mutect2, varscan2
- ZBED1 | c.964T>G p.F322V | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV100585504; called by muse, mutect2, varscan2
- ZC3H6 | c.2068del p.A690Hfs*28 | Frame Shift Del (DEL) | VAF 15/45 reads (33%) | catalogued as COSV59670033; called by mutect2, pindel, varscan2
- ZFHX3 | c.3758G>A p.R1253H | Missense Mutation (SNP) | VAF 26/53 reads (49%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.924); catalogued as rs370933867; called by muse, mutect2, varscan2
- ZFYVE28 | c.702-1G>T p.X234_splice | Splice Site (SNP) | VAF 8/32 reads (25%) | catalogued as COSV99342852; called by muse, mutect2, varscan2
- ZMYND8 | c.1975G>T p.D659Y (on ENST00000311275 / NM_001363741.2; = p.D679Y on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/159 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.886); catalogued as COSV99520234; called by muse, mutect2, varscan2
- ZNF208 | c.2520A>T p.K840N | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV101237002; called by muse, mutect2, varscan2
- ZNF235 | c.1247C>G p.S416* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as COSV99349407; called by muse, mutect2, varscan2
- ZNF260 | c.815G>T p.G272V | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101591049; called by muse, mutect2, varscan2
- ZNF280A | c.265C>A p.P89T | Missense Mutation (SNP) | VAF 25/156 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.278); catalogued as COSV100131028; called by muse, mutect2, varscan2
- ZNF304 | c.91C>A p.L31I | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56586839, COSV99988589; called by muse, mutect2, varscan2
- ZNF385D | c.38G>T p.S13I | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV99874454; called by muse, mutect2, varscan2
- ZNF41 | c.2208G>A p.M736I | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.015); catalogued as COSV100492009; called by muse, mutect2, varscan2
- ZNF467 | c.362C>G p.P121R | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.656); catalogued as COSV100117906; called by muse, mutect2
- ZNF571 | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 11/192 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.76); catalogued as COSV100143719; called by muse, mutect2
- ZNF695 | c.284A>G p.D95G | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100377415; called by muse, mutect2
- ZNF804A | c.2462C>A p.P821H | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV56454847, COSV56471273; called by muse, mutect2, varscan2
- ZNF827 | c.2011A>C p.K671Q | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as COSV101061306; called by muse, mutect2, varscan2
- ZNFX1 | c.2123C>T p.P708L | Missense Mutation (SNP) | VAF 54/106 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100870818; called by muse, mutect2, varscan2
- ZSCAN10 | c.1043C>T p.P348L (on ENST00000252463; = p.P403L on NM_032805.3) | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV99374006; called by muse, mutect2, varscan2
- ZSCAN21 | c.646G>C p.E216Q | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV99460896; called by muse, mutect2, varscan2
- CPXM2 | c.308A>G p.K103R | Missense Mutation (SNP) | VAF 5/89 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2
- FOXD4L5 | c.901C>A p.P301T | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by mutect2, varscan2
- GPR179 | c.5188A>C p.N1730H (on ENST00000621958; = p.N1729H on NM_001004334.4) | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- IGHV3-38 | c.198G>T p.W66C | Missense Mutation (SNP) | VAF 44/140 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.585); called by muse, varscan2
- IGHV4-28 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 45/143 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.105); called by muse, varscan2
- IGKV1D-17 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 49/311 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IGKV3D-15 | c.16C>T p.Q6* | Nonsense Mutation (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- IGKV6D-41 | c.34C>A p.L12I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- IRF9 | c.921_944del p.G308_P315del | In Frame Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel
- IRX2 | c.1413del p.*472Rfs*93 | Frame Shift Del (DEL) | VAF 8/78 reads (10%) | called by mutect2, pindel
- LRP1B | c.2029G>C p.E677Q | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2
- PKP2 | c.308dup p.V104Cfs*3 | Frame Shift Ins (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.2158A>T p.T720S | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT tolerated (0.84); PolyPhen benign (0.001); called by muse, mutect2
- RANBP2 | c.6482G>T p.G2161V | Missense Mutation (SNP) | VAF 8/204 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- RNMT | c.1234_1240del p.L412Efs*31 | Frame Shift Del (DEL) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- RTL9 | c.3979A>G p.T1327A | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SLC26A5 | c.1582G>T p.E528* | Nonsense Mutation (SNP) | VAF 12/46 reads (26%) | called by muse, mutect2
- SLC9B2 | c.713_713+1dup p.X238_splice | Splice Site (INS) | VAF 4/24 reads (17%) | called by mutect2, pindel
- THRB | c.460del p.D154Tfs*38 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | called by mutect2, pindel*, varscan2*
- TTN | c.97092dup p.Y32365Ifs*13 (on ENST00000591111; = p.Y24941Ifs*13 on NM_003319.4) | Frame Shift Ins (INS) | VAF 14/77 reads (18%) | called by mutect2, pindel, varscan2
- ZBTB8A | c.889del p.L297* | Frame Shift Del (DEL) | VAF 44/107 reads (41%) | called by mutect2, pindel, varscan2
- ZFHX3 | c.1382_1386del p.E461Gfs*39 | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | called by mutect2, pindel, varscan2
- ZNF148 | c.772G>C p.E258Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.808); called by muse, mutect2
- ABTB1 | c.489C>T p.P163= (on ENST00000232744 / NM_172027.3; = p.P21= on NM_032548.3) | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as rs368348243; called by muse, mutect2, varscan2
- ACOX3 | c.357C>A p.A119= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV100711943; called by muse, mutect2, varscan2
- ACTRT1 | c.355C>A p.R119= | Silent (SNP) | VAF 49/215 reads (23%) | catalogued as COSV100947568, COSV64419153; called by muse, mutect2, varscan2
- ARHGEF11 | c.3855G>T p.L1285= | Silent (SNP) | VAF 17/44 reads (39%) | catalogued as rs1346266405, COSV100168523; called by muse, mutect2, varscan2
- BASP1 | c.576G>A p.A192= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as rs971627344, COSV59469620; called by muse, mutect2
- BICRA | c.1674C>T p.P558= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as rs764342455, COSV101194300; called by muse, mutect2, varscan2
- BIRC6 | c.9282C>G p.A3094= | Silent (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- BSPRY | c.580T>C p.L194= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as COSV100949518; called by muse, mutect2, varscan2
- C8orf37 | c.105C>T p.G35= | Silent (SNP) | VAF 79/288 reads (27%) | catalogued as rs1464210060, COSV99713118; called by muse, mutect2, varscan2
- CACNG5 | c.150C>A p.I50= | Silent (SNP) | VAF 23/101 reads (23%) | catalogued as COSV50062864; called by muse, mutect2, varscan2
- CBX4 | c.1587G>C p.S529= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV53964322, COSV53966212, COSV99490315; called by muse, mutect2, varscan2
- CCNB3 | c.3562C>T p.L1188= | Silent (SNP) | VAF 35/123 reads (28%) | catalogued as COSV99328902; called by muse, mutect2, varscan2
- CDH2 | c.1966C>A p.R656= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs200324494, COSV52285699, COSV99296629; called by muse, mutect2, varscan2
- CELSR1 | c.4722C>T p.I1574= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as rs150880121; called by muse, mutect2, varscan2
- CLIP2 | c.2454G>T p.T818= | Silent (SNP) | VAF 36/134 reads (27%) | catalogued as rs137858493, COSV56276126; called by muse, mutect2, varscan2
- CNST | c.1050C>T p.S350= | Silent (SNP) | VAF 28/119 reads (24%) | catalogued as COSV100830045; called by muse, mutect2, varscan2
- CSF3R | c.2451C>A p.L817= | Silent (SNP) | VAF 6/15 reads (40%) | catalogued as COSV100117645; called by muse, mutect2, varscan2
- DCLRE1C | c.735C>T p.L245= (on ENST00000378278 / NM_001350965.2; = p.L130= on NM_022487.4) | Silent (SNP) | VAF 12/112 reads (11%) | catalogued as COSV100739793; called by muse, mutect2
- DDX60 | c.531G>T p.G177= | Silent (SNP) | VAF 5/45 reads (11%) | catalogued as COSV101190432, COSV101190500; called by muse, mutect2, varscan2
- DGKE | c.558C>A p.I186= | Silent (SNP) | VAF 13/60 reads (22%) | catalogued as COSV99400901; called by muse, mutect2, varscan2
- DIP2A | c.2868G>A p.G956= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as COSV100595682; called by muse, mutect2, varscan2
- DLEC1 | c.3225G>T p.V1075= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100342075; called by muse, mutect2, varscan2
- ERP44 | c.24C>T p.S8= | Silent (SNP) | VAF 20/55 reads (36%) | catalogued as rs767833177, COSV99316369; called by muse, mutect2, varscan2
- ESRRG | c.774C>A p.P258= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as COSV100752769; called by muse, mutect2, varscan2
- FAIM2 | c.807G>T p.L269= | Silent (SNP) | VAF 13/40 reads (33%) | catalogued as COSV100277513; called by muse, mutect2, varscan2
- FAM47C | c.1197G>T p.V399= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV100792479; called by muse, mutect2, varscan2
- FAT3 | c.9645C>A p.S3215= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV99965307; called by muse, mutect2, varscan2
- GLI1 | c.58C>A p.R20= | Silent (SNP) | VAF 20/62 reads (32%) | catalogued as COSV57362749, COSV99954061; called by muse, mutect2, varscan2
- GNPTAB | c.225T>A p.I75= | Silent (SNP) | VAF 22/178 reads (12%) | catalogued as COSV100171954; called by muse, mutect2, varscan2
- GPR160 | c.477C>T p.A159= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs760827793, COSV100576119; called by muse, mutect2, varscan2
- GRIA1 | c.477G>A p.Q159= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as COSV53589348; called by muse, mutect2, varscan2
- GRIK2 | c.18G>T p.P6= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV100025489, COSV59758434; called by muse, mutect2, varscan2
- GRK2 | c.973C>T p.L325= | Silent (SNP) | VAF 11/88 reads (13%) | catalogued as rs993722198, COSV100419654; called by muse, mutect2, varscan2
- HIPK3 | c.714T>G p.G238= | Silent (SNP) | VAF 5/73 reads (7%) | catalogued as COSV100305668; called by muse, mutect2
- HOXB13 | c.651C>T p.R217= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV99284847; called by muse, mutect2, varscan2
- IGKV3-20 | c.84A>T p.P28= | Silent (SNP) | VAF 41/109 reads (38%) | catalogued as rs751608157; called by muse, mutect2, varscan2
- IGLC2 | c.225G>A p.T75= | Silent (SNP) | VAF 31/87 reads (36%) | catalogued as rs765458895; called by muse, mutect2, varscan2
- KDM5C | c.3027G>A p.A1009= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs782659319, COSV100949076; called by muse, mutect2, varscan2
- KIF14 | c.4227C>A p.V1409= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as COSV100950805; called by muse, mutect2, varscan2
- KIF21B | c.2676C>A p.T892= | Silent (SNP) | VAF 29/106 reads (27%) | catalogued as COSV100144401; called by muse, mutect2, varscan2
- KIF5C | c.1488C>A p.V496= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV101276129; called by muse, mutect2, varscan2
- KRT6C | c.501C>A p.I167= | Silent (SNP) | VAF 23/106 reads (22%) | catalogued as COSV99359938; called by muse, mutect2, varscan2
- KRTAP26-1 | c.450C>T p.S150= | Silent (SNP) | VAF 37/140 reads (26%) | catalogued as COSV100860410; called by muse, mutect2, varscan2
- LRRK2 | c.6408A>G p.E2136= | Silent (SNP) | VAF 10/45 reads (22%) | catalogued as COSV100109993; called by muse, mutect2, varscan2
- MAK | c.1128C>T p.V376= | Silent (SNP) | VAF 16/184 reads (9%) | catalogued as rs768120333, COSV100504384, COSV100504797; ClinVar: uncertain significance; called by muse, mutect2
- MAP3K12 | c.1809C>G p.L603= | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV99913195; called by muse, mutect2, varscan2
- MICAL2 | c.5337G>A p.K1779= | Silent (SNP) | VAF 33/175 reads (19%) | catalogued as COSV99811690; called by muse, mutect2, varscan2
- MMRN1 | c.363T>A p.A121= | Silent (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99307021; called by muse, mutect2, varscan2
- MOXD1 | c.648G>A p.K216= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs749080021, COSV60947216; called by muse, mutect2, varscan2
- MRGPRX1 | c.433C>T p.L145= | Silent (SNP) | VAF 34/179 reads (19%) | catalogued as rs369697424; called by muse, mutect2, varscan2
- MRGPRX2 | c.910C>T p.L304= | Silent (SNP) | VAF 44/111 reads (40%) | catalogued as COSV100316724; called by muse, mutect2, varscan2
- MRO | c.717G>A p.L239= | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs558247458, COSV99839200; called by mutect2, varscan2
- MUC16 | c.17529C>A p.T5843= | Silent (SNP) | VAF 44/117 reads (38%) | catalogued as COSV101199601, COSV67474174; called by muse, mutect2, varscan2
- MXRA5 | c.1569G>T p.A523= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as COSV54249997, COSV99476713; called by muse, mutect2, varscan2
- MYO9A | c.1662T>C p.I554= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as COSV100613260; called by muse, mutect2
- NDRG3 | c.864G>A p.A288= (on ENST00000349004 / NM_032013.4; = p.A276= on NM_022477.4) | Silent (SNP) | VAF 13/69 reads (19%) | catalogued as rs371140287; called by muse, mutect2, varscan2
- OR4A15 | c.369C>G p.A123= | Silent (SNP) | VAF 52/216 reads (24%) | catalogued as COSV100124034; called by muse, mutect2, varscan2
- OR52R1 | c.99G>T p.P33= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as COSV61887757, COSV61889205; called by muse, mutect2, varscan2
- OR8J3 | c.729G>A p.S243= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as rs774862778, COSV56879581, COSV56879736; called by muse, mutect2, varscan2
- P2RY8 | c.276G>T p.G92= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as COSV101183995; called by muse, mutect2, varscan2
- PCDH15 | c.4644C>A p.A1548= | Silent (SNP) | VAF 58/128 reads (45%) | catalogued as COSV100903925; called by muse, mutect2, varscan2
- PGLYRP2 | c.1209G>T p.P403= | Silent (SNP) | VAF 4/31 reads (13%) | catalogued as COSV52994337, COSV52997973; called by muse, mutect2, varscan2
- PMFBP1 | c.1659G>A p.R553= (on ENST00000537465; = p.R548= on NM_031293.3) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV99400729; called by muse, mutect2, varscan2
- PPARGC1B | c.2184T>C p.P728= | Silent (SNP) | VAF 32/84 reads (38%) | catalogued as COSV100494686; called by muse, mutect2, varscan2
- PRKACA | c.513G>A p.E171= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as COSV100432012; called by muse, mutect2, varscan2
- RGL1 | c.1755T>G p.S585= (on ENST00000360851 / NM_001297672.2; = p.S620= on NM_015149.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 47/183 reads (26%) | catalogued as rs766042880, COSV100486579; called by muse, mutect2, varscan2
- RYR2 | c.9672C>A p.S3224= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as COSV100769743; called by muse, mutect2, varscan2
- SERPINB12 | c.675G>T p.T225= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as COSV54033165, COSV99501624; called by muse, mutect2, varscan2
- SERPINI2 | c.183G>C p.L61= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as COSV99247868; called by muse, mutect2, varscan2
- SLC12A6 | c.627A>G p.T209= (on ENST00000354181 / NM_001365088.1; = p.T158= on NM_005135.2) | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs779557719, COSV99271811; called by muse, mutect2, varscan2
- SLC13A5 | c.1110G>C p.V370= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as COSV99545863; called by muse, mutect2, varscan2
- SLC25A24 | c.600A>C p.A200= | Silent (SNP) | VAF 42/86 reads (49%) | catalogued as COSV99916178; called by muse, mutect2, varscan2
- SLC30A7 | c.112C>T p.L38= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV100725472; called by muse, mutect2
- SLC8A1 | c.2160T>C p.Y720= | Silent (SNP) | VAF 59/158 reads (37%) | catalogued as rs760173611, COSV100245730; called by muse, mutect2, varscan2
- SLC9A7 | c.2073G>A p.T691= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as rs868709707, COSV60382377; called by muse, mutect2, varscan2
- SLITRK2 | c.456G>T p.G152= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as COSV100157657; called by muse, mutect2, varscan2
- SPPL2B | c.879G>A p.P293= | Silent (SNP) | VAF 19/43 reads (44%) | catalogued as rs1461155803, COSV101194593; called by muse, mutect2, varscan2
- SUGP2 | c.2733G>T p.G911= | Silent (SNP) | VAF 12/31 reads (39%) | catalogued as COSV100431840; called by muse, mutect2, varscan2
- TBX5 | c.1464C>A p.L488= | Silent (SNP) | VAF 7/47 reads (15%) | catalogued as COSV100091113; called by muse, mutect2, varscan2
- TMC2 | c.591C>T p.A197= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as COSV100727544; called by muse, mutect2, varscan2
- TMEM132D | c.2658C>T p.T886= | Silent (SNP) | VAF 16/100 reads (16%) | catalogued as COSV101242781; called by muse, mutect2, varscan2
- TMEM177 | c.513G>T p.L171= | Silent (SNP) | VAF 13/76 reads (17%) | catalogued as COSV99733599; called by muse, mutect2, varscan2
- TPP2 | c.135G>A p.T45= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs373143538; called by muse, mutect2, varscan2
- TRAV8-3 | c.111A>T p.S37= | Silent (SNP) | VAF 8/21 reads (38%) | called by muse, mutect2, varscan2
- TRIM51 | c.1251T>C p.G417= | Silent (SNP) | VAF 51/142 reads (36%) | catalogued as COSV99792518; called by muse, varscan2
- TRO | c.585C>T p.A195= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99436282; called by muse, mutect2, varscan2
- TSHZ3 | c.2034C>T p.C678= | Silent (SNP) | VAF 11/82 reads (13%) | catalogued as COSV99551357; called by muse, mutect2, varscan2
- TTC23L | c.363C>T p.G121= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as rs1013072768, COSV101551120; called by muse, mutect2, varscan2
- TTR | c.426C>A p.V142= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV99379500; called by muse, mutect2, varscan2
- TYR | c.264C>G p.T88= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99633984; called by muse, mutect2, varscan2
- VTN | c.606C>A p.I202= | Silent (SNP) | VAF 34/82 reads (41%) | catalogued as COSV56874241, COSV99879636; called by muse, mutect2, varscan2
- WWC3 | c.1851C>A p.L617= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as COSV101081384; called by muse, mutect2, varscan2
- ZNF280B | c.831G>A p.K277= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as COSV100840260; called by muse, mutect2, varscan2
- ZNF823 | c.1338T>C p.C446= (on ENST00000341191 / NM_001297610.2; = p.C402= on NM_017507.2) | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100362480; called by muse, mutect2
- AC073310.1 | n.1026G>T | RNA (SNP) | VAF 5/61 reads (8%) | called by muse, mutect2
- AC073310.1 | n.1027G>T | RNA (SNP) | VAF 5/60 reads (8%) | called by muse, mutect2
- ATE1 | c.942+1004C>G | Intron (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- EPHA6 | c.1895-8913A>T | Intron (SNP) | VAF 15/69 reads (22%) | catalogued as COSV101062232; called by muse, mutect2, varscan2
- HLA-DRB9 | n.192C>T | RNA (SNP) | VAF 10/128 reads (8%) | catalogued as rs536455652; called by muse, mutect2
- WASF4P | n.1075C>G | RNA (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2, varscan2
- ZNF511 | c.*860G>T | 3'UTR (SNP) | VAF 91/202 reads (45%) | catalogued as COSV100756774; called by muse, mutect2, varscan2
